CCDI case PBCAKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/282a8a79-3809-4561-b343-b3c512994e30

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,303 days).

Biospecimens (3 samples)
- Sample 0DPCXN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPCXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DPCY0: Tissue type: Tumor; Specimen type: Solid Tissue.
